Somatic mutation profile of tumor specimen TCGA-VS-A94Z-01A (aliquot TCGA-VS-A94Z-01A-11D-A387-09) from TCGA case TCGA-VS-A94Z, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 38.5 years (14,046 days).
Specimen TCGA-VS-A94Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb19ddbb-5ffb-43d6-ab44-a18b95b86304.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A94Z-10A (Blood Derived Normal), aliquot TCGA-VS-A94Z-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/843d122f-a923-44d6-8fc6-a56204639e2b

The open-access MAF lists 807 somatic variants for this specimen: 605 protein-altering or splice-affecting, 184 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 445, Silent 184, Frame Shift Del 90, Nonsense Mutation 33, Frame Shift Ins 20, Splice Site 8, Intron 6, RNA 6, Splice Region 5, In Frame Del 3, 3'Flank 2, 5'UTR 2.

Variants (750 of 807; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTLA4 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as rs886041906, COSV55591750, COSV99865404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs794728325, CM091205, CM091206, CS013965, COSV57313335; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AACS | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs552206706, COSV55538790, COSV99908323; called by muse, mutect2, varscan2
- ABCA12 | c.6713G>A p.R2238Q (on ENST00000272895 / NM_173076.3; = p.R1920Q on NM_015657.3) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs559960979, COSV55958787; called by muse, mutect2, varscan2
- ABCA12 | c.6327dup p.G2110Wfs*3 (on ENST00000272895 / NM_173076.3; = p.G1792Wfs*3 on NM_015657.3) | Frame Shift Ins (INS) | VAF 11/63 reads (17%) | catalogued as rs1204636023; called by mutect2, pindel, varscan2
- ABCF1 | c.695_697del p.G232del | In Frame Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1158575381; called by mutect2, pindel, varscan2
- ACE | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs989791368, COSV52007304; called by muse, mutect2
- ACSL1 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99860856; called by muse, mutect2, varscan2
- ACSL4 | c.1821-3dup | Splice Region (INS) | VAF 9/57 reads (16%) | catalogued as rs748641243; called by mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAMTS17 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs201484140; called by mutect2, varscan2
- ADGRE2 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100216343; called by muse, mutect2, varscan2
- ADGRL4 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.102); catalogued as COSV100876382; called by muse, mutect2
- ADNP | c.1368del p.P457Lfs*21 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | catalogued as COSV62426069; called by mutect2, pindel, varscan2
- ADRA1D | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221990067, COSV101063100; called by muse, mutect2, varscan2
- ADRA2C | c.1320C>A p.F440L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100342765; called by muse, mutect2, varscan2
- AFDN | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as COSV100653336; called by muse, mutect2, varscan2
- AFDN | c.3352G>T p.G1118C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100653338; called by muse, mutect2, varscan2
- AGGF1 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as rs370192876; called by mutect2, varscan2
- AGRN | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV101038997; called by mutect2, varscan2
- AHCTF1 | c.2010G>C p.L670F (on ENST00000366508; = p.L644F on NM_015446.5) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV100404180; called by muse, mutect2, varscan2
- AHCYL1 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100779648; called by muse, mutect2, varscan2
- AHI1 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99663400; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR7A3 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV100853826; called by muse, mutect2, varscan2
- ALMS1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100043297; called by muse, varscan2
- ALX4 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100241199; called by muse, mutect2, varscan2
- ANKRD34A | c.607C>G p.R203G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as COSV100041361; called by muse, mutect2, varscan2
- ANO3 | c.2847G>C p.E949D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99884646; called by muse, mutect2, varscan2
- ANO7 | c.2041G>A p.A681T (on ENST00000274979; = p.A627T on NM_001370694.2) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.037); catalogued as rs770239303, COSV99239090; called by muse, mutect2, varscan2
- ANTXR1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100362884; called by muse, mutect2, varscan2
- AP000350.4 | c.589G>C p.A197P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); catalogued as COSV53158896; called by muse, mutect2
- AP5B1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as COSV100376124; called by mutect2, varscan2
- APOBEC3F | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs765588856, COSV100415242; called by muse, mutect2, varscan2
- ARAP3 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99500103; called by muse, mutect2, varscan2
- ARCN1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs367554879; called by muse, mutect2, varscan2
- ARHGAP11A | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs751204257, COSV100853315; called by muse, mutect2, varscan2
- ARHGAP26 | c.1994del p.P665Rfs*135 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs1298538973; called by mutect2, pindel, varscan2
- ARHGAP45 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV57436781; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs781483073; called by pindel, varscan2
- ARHGEF2 | c.1658C>T p.T553I (on ENST00000361247 / NM_001162383.2; = p.T525I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100560941; called by muse, mutect2, varscan2
- ARMC5 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs762231889, COSV51655532; called by muse, mutect2, varscan2
- ARMCX1 | c.1204A>G p.N402D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV100863230; called by muse, mutect2, varscan2
- ARX | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as CM164469, COSV100984072; called by muse, mutect2, varscan2
- ASAP3 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369316; called by muse, mutect2, varscan2
- ASNS | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99446609; called by muse, mutect2, varscan2
- ATG2A | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as rs145534182; called by muse, mutect2, varscan2
- ATP11A | c.2476G>T p.G826C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369512; called by muse, mutect2, varscan2
- ATP1A1 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99814444; called by muse, mutect2, varscan2
- ATP6V1E1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99494409; called by muse, mutect2, varscan2
- ATXN2 | c.1820C>A p.P607H (on ENST00000550104; = p.P447H on NM_002973.4) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV101112885; called by muse, mutect2, varscan2
- AURKC | c.922G>T p.A308S (on ENST00000302804 / NM_001015878.2; = p.A274S on NM_003160.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100248947; called by muse, mutect2, varscan2
- AVPR2 | c.888G>T p.W296C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509626; called by muse, mutect2, varscan2
- BAG5 | c.1308C>G p.S436R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV99914981; called by muse, mutect2
- BAZ2A | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV99467283; called by muse, mutect2, varscan2
- BBS7 | c.90_91del p.R30Sfs*11 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs1291044978; called by pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND5 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs746087223, COSV100884133; called by muse, mutect2, varscan2
- BIRC6 | c.12577G>C p.D4193H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428574; called by muse, mutect2
- BLNK | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV56409950, COSV99814121; called by muse, mutect2, varscan2
- BLZF1 | c.962del p.K321Rfs*21 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs1557849884; called by mutect2, pindel, varscan2
- BSN | c.8920G>A p.A2974T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753949712, COSV99609426; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | catalogued as rs752512017; called by mutect2, varscan2
- BTK | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as rs782731222, COSV58119150; called by muse, mutect2, varscan2
- C12orf4 | c.707del p.N236Tfs*22 | Frame Shift Del (DEL) | VAF 20/130 reads (15%) | catalogued as COSV54210606; called by mutect2, pindel, varscan2
- C1QL3 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1260391937, COSV100126973, COSV54348074; called by muse, mutect2, varscan2
- C1orf74 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs756614987; called by muse, mutect2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C3 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55573977; called by muse, mutect2
- C7orf26 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100732976; called by muse, mutect2, varscan2
- CACNA1S | c.1242G>C p.W414C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100755233; called by muse, mutect2, varscan2
- CACNB1 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100703515; called by muse, mutect2, varscan2
- CCAR2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51515309; called by muse, mutect2
- CCDC105 | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1254954294, COSV99480037; called by muse, mutect2
- CD1A | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs199910842, COSV56860615; called by muse, mutect2, varscan2
- CDC40 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100309506, COSV104410431; called by muse, mutect2, varscan2
- CDHR1 | c.827del p.G276Afs*11 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV60565872; called by mutect2, pindel
- CDK1 | c.545C>G p.S182* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100358890; called by muse, mutect2, varscan2
- CDKL5 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs376429571, COSV101184422; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CENPE | c.5934dup p.E1979Rfs*6 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs1350400778; called by mutect2, pindel, varscan2
- CENPF | c.858G>C p.Q286H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100871865; called by muse, mutect2, varscan2
- CENPF | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100871866; called by muse, mutect2, varscan2
- CEP85L | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.219); catalogued as COSV100874306; called by muse, mutect2
- CGB7 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100655100; called by muse, mutect2, varscan2
- CHD2 | c.5288G>A p.R1763H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV67708273; called by muse, mutect2, varscan2
- CHEK2 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs1483975421, COSV100102253; called by muse, varscan2
- CHPF2 | c.908T>C p.F303S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV99223284; called by muse, mutect2, varscan2
- CHRNA9 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1342521367, COSV59573400; called by muse, mutect2, varscan2
- CHTF18 | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99243380; called by muse, mutect2, varscan2
- CLCA2 | c.2736G>C p.L912F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100991653; called by muse, mutect2, varscan2
- CLCN4 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV101073962; called by muse, mutect2
- CLIC1 | c.382+2T>C p.X128_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV101007543; called by muse, mutect2, varscan2
- CNOT1 | c.3121A>G p.T1041A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99800881; called by muse, mutect2, varscan2
- CNOT2 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.459); catalogued as rs750913052, COSV57506089; called by muse, mutect2, varscan2
- CNR2 | c.1060G>T p.D354Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.094); catalogued as COSV100991557; called by muse, mutect2, varscan2
- CNTRL | c.369del p.K123Nfs*8 | Frame Shift Del (DEL) | VAF 6/67 reads (9%) | catalogued as COSV53047442; called by mutect2, pindel
- COL18A1 | c.3217G>A p.A1073T (on ENST00000359759 / NM_130444.3; = p.A838T on NM_030582.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.481); catalogued as COSV100645396; called by muse, mutect2, varscan2
- COL2A1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs763538232, COSV100477168; called by muse, mutect2, varscan2
- COL3A1 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100483552; called by muse, mutect2, varscan2
- COL5A1 | c.4795G>A p.E1599K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as rs149212775, COSV65668143; called by muse, mutect2, varscan2
- COL6A3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs905662421, COSV55087815, COSV55109749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.3291G>C p.R1097S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100650705; called by muse, mutect2, varscan2
- COPA | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616448; called by muse, mutect2, varscan2
- CPA4 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); catalogued as rs372031946; called by muse, mutect2, varscan2
- CPAMD8 | c.3092G>A p.R1031H (on ENST00000651564; = p.R984H on NM_015692.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.062); catalogued as rs770629728, COSV101488365, COSV71597371; called by mutect2, varscan2
- CPD | c.2782C>A p.L928M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.736); catalogued as COSV99853160; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CR2 | c.2089C>G p.Q697E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs779357644, COSV100889685; called by muse, mutect2, varscan2
- CRHR2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs200310748, COSV59264109; called by mutect2, varscan2
- CRISP1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV59994604; called by muse, mutect2, varscan2
- CSF3R | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV58967833; called by muse, mutect2, varscan2
- CSNK1A1L | c.690dup p.Q231Tfs*4 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | catalogued as rs369743261; called by mutect2, varscan2
- CTNS | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV99251483; called by mutect2, varscan2
- CTU2 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99966382; called by muse, mutect2, varscan2
- CUL4A | c.1372G>A p.A458T (on ENST00000375440 / NM_001008895.4; = p.A358T on NM_003589.3) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100417460; called by muse, mutect2, varscan2
- CUX1 | c.1675G>A p.G559S (on ENST00000437600 / NM_181500.4; = p.G561S on NM_001913.5) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as rs781791032, COSV99476480; called by muse, mutect2
- CXADR | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV53028949; called by muse, mutect2, varscan2
- CYP19A1 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs201638381, COSV99547951; called by muse, varscan2
- CYP1A2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746644895, COSV59659632; called by muse, mutect2, varscan2
- CYP46A1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs982956449, COSV99952784; called by muse, mutect2, varscan2
- DAZAP1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | catalogued as COSV99245421; called by muse, mutect2
- DDX28 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV100193084; called by muse, mutect2, varscan2
- DENND3 | c.69del p.R24Efs*44 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as COSV52801617, COSV52802725; called by mutect2, pindel, varscan2
- DENND4B | c.304del p.L102Sfs*197 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs747842790; called by pindel, varscan2
- DENND5B | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV60903679; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs35538077; called by pindel, varscan2
- DGKK | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV101053151; called by muse, mutect2
- DHRS13 | c.1018dup p.H340Pfs*3 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | catalogued as rs751737771; called by pindel, varscan2
- DHX30 | c.773C>T p.S258L (on ENST00000445061 / NM_138615.3; = p.S219L on NM_014966.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV100820090; called by muse, mutect2, varscan2
- DHX38 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs184511349; called by muse, mutect2, varscan2
- DIDO1 | c.4267G>C p.E1423Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV99826668; called by muse, mutect2, varscan2
- DISP1 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99451781; called by muse, mutect2, varscan2
- DMWD | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs757145788, COSV99353560; called by muse, varscan2
- DNAH10 | c.12482G>A p.R4161H (on ENST00000409039; = p.R4100H on NM_207437.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760522821, COSV68996140; called by muse, mutect2, varscan2
- DNAH5 | c.9776T>C p.V3259A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99452512; called by muse, mutect2, varscan2
- DNAH7 | c.8509G>T p.A2837S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV100416672; called by muse, mutect2, varscan2
- DNAH8 | c.8270T>C p.V2757A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100546670; called by muse, mutect2, varscan2
- DNAH9 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV52339016, COSV52345524; called by muse, mutect2, varscan2
- DNAH9 | c.5432G>A p.R1811H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772276258, COSV99302993; called by muse, mutect2, varscan2
- DNTTIP2 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100785198; called by muse, mutect2, varscan2
- DOCK5 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as rs771599318, COSV52414305; called by muse, mutect2, varscan2
- DOP1A | c.6671dup p.R2225Qfs*37 | Frame Shift Ins (INS) | VAF 23/73 reads (32%) | catalogued as rs773223967; called by mutect2, pindel, varscan2
- DPP10 | c.2094A>T p.E698D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.013); catalogued as COSV100065107, COSV100070166; called by muse, mutect2
- DPPA5 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV64875634, COSV64875772; called by muse, mutect2, varscan2
- DRAXIN | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201196094, COSV53845889; called by muse, mutect2, varscan2
- DRD5 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100431969; called by muse, mutect2
- DSC1 | c.1988G>C p.R663T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs199628832, COSV99938050; called by muse, mutect2, varscan2
- DST | c.12647C>T p.A4216V (on ENST00000361203 / NM_001374722.1; = p.A1804V on NM_015548.5) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1484781372, COSV54995978; called by muse, mutect2, varscan2
- DYNC2H1 | c.10499G>A p.S3500N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62108720; called by muse, mutect2, varscan2
- E2F7 | c.976A>G p.S326G | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100523766; called by muse, mutect2, varscan2
- ECHDC2 | c.718C>T p.R240W (on ENST00000371522 / NM_001198961.2; = p.R209W on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1424460440, COSV100597704; called by muse, mutect2, varscan2
- EHMT1 | c.3733C>T p.R1245C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1413598240, COSV101135076; called by muse, mutect2, varscan2
- ELF4 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs1055282581, COSV100257533; called by muse, mutect2, varscan2
- ELOF1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV52947814; called by muse, mutect2, varscan2
- ENGASE | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs758339425, COSV100285907; called by muse, mutect2, varscan2
- ENOX2 | c.1431G>C p.K477N (on ENST00000338144 / NM_001382520.1; = p.K448N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100584459; called by muse, mutect2, varscan2
- EPG5 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957818; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.818); catalogued as rs762116131, COSV99212585; called by muse, mutect2, varscan2
- ERVW-1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV101423860; called by muse, mutect2, varscan2
- ETV4 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs776306922, COSV100081499, COSV60043769; called by muse, mutect2, varscan2
- EXOC4 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs767674208, COSV54085771, COSV99555042; called by muse, mutect2, varscan2
- FADD | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.203); catalogued as COSV57229606; called by mutect2, varscan2
- FAM120C | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100070359; called by muse, mutect2, varscan2
- FAM155B | c.554del p.N185Tfs*40 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM47A | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.794); catalogued as COSV100649927, COSV60500943; called by muse, mutect2, varscan2
- FAM83C | c.1053C>G p.I351M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100981641; called by muse, mutect2, varscan2
- FASTKD1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV101328528; called by muse, mutect2, varscan2
- FASTKD1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101328529; called by muse, mutect2, varscan2
- FBXO27 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99494727; called by muse, mutect2, varscan2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2, varscan2
- FKBP8 | c.868G>A p.A290T (on ENST00000222308 / NM_001308373.2; = p.A291T on NM_012181.5) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as COSV55893524; called by mutect2, varscan2
- FLNA | c.7552G>T p.G2518C (on ENST00000369850 / NM_001110556.2; = p.G2510C on NM_001456.3) | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100775002; called by muse, mutect2, varscan2
- FLRT2 | c.1812A>C p.E604D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as COSV100420789; called by muse, mutect2, varscan2
- FLT1 | c.3660G>C p.M1220I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56745343, COSV99164807; called by muse, mutect2, varscan2
- FN3KRP | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs939258008, COSV99485076; called by muse, mutect2, varscan2
- FNDC1 | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99796378; called by muse, mutect2, varscan2
- FOXA2 | c.1283C>T p.T428M (on ENST00000377115 / NM_153675.3; = p.T434M on NM_021784.5) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV101008442; called by muse, mutect2, varscan2
- FOXJ1 | c.167del p.G56Afs*65 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs1171683734, COSV53946218; called by mutect2, varscan2
- FOXN3 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99727002; called by muse, mutect2, varscan2
- FUBP1 | c.1338G>C p.K446N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99629353; called by muse, mutect2, varscan2
- FXR1 | c.171del p.E58Kfs*8 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as rs1559986435; called by mutect2, pindel, varscan2
- GAB4 | c.1312A>G p.R438G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV101272065, COSV101272066; called by muse, mutect2, varscan2
- GALNT8 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as rs375631897; called by muse, mutect2, varscan2
- GARRE1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100209639; called by muse, mutect2, varscan2
- GEMIN7 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs977717051; called by muse, mutect2
- GFPT2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99517955; called by muse, mutect2, varscan2
- GGTLC1 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99600847; called by muse, mutect2
- GIMAP4 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.159); catalogued as rs760145799, COSV55434111, COSV99751071; called by muse, mutect2, varscan2
- GLI4 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60681656; called by muse, mutect2, varscan2
- GLUD2 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100047017; called by muse, mutect2, varscan2
- GNB1 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV101060847; called by muse, mutect2
- GNG12 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV63973163; called by muse, mutect2
- GP2 | c.1172C>T p.T391I (on ENST00000381362 / NM_001007240.3; = p.T388I on NM_001502.4) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs1355874138, COSV100221596; called by muse, mutect2
- GPR108 | c.1095G>C p.K365N (on ENST00000264080 / NM_001080452.1; = p.K123N on NM_020171.2) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901479; called by muse, mutect2, varscan2
- GPR149 | c.401T>C p.M134T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1338151449, COSV101078640; called by muse, mutect2, varscan2
- GPR50 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV99505691; called by muse, mutect2, varscan2
- GPSM3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs749245400; called by muse, mutect2, varscan2
- GRIA4 | c.1681G>A p.V561I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99233605; called by muse, mutect2, varscan2
- GRIN2A | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100410648, COSV58049732; called by muse, mutect2, varscan2
- GRIN2D | c.1951del p.R651Gfs*31 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as COSV54381864; called by mutect2, pindel, varscan2
- GSTZ1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774523538, COSV53623014; called by muse, mutect2, varscan2
- GTF2F1 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101081345; called by muse, mutect2, varscan2
- GTF2H4 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs1183122752, COSV99462080; called by mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as rs1231771183; called by mutect2, varscan2
- GYG2 | c.7+2T>C p.X3_splice | Splice Site (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100089198; called by muse, mutect2, varscan2
- HAUS8 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99505441; called by muse, mutect2, varscan2
- HDAC9 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as COSV101286907; called by muse, mutect2, varscan2
- HECTD3 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV64670097; called by muse, mutect2, varscan2
- HK1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274082913, COSV100067512; called by muse, mutect2, varscan2
- HLA-B | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 28/63 reads (44%) | catalogued as COSV69520575, COSV69520821; called by muse, mutect2
- HLA-F | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as COSV99466273; called by muse, mutect2, varscan2
- HMCN1 | c.3649C>T p.H1217Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as COSV99633559; called by muse, mutect2, varscan2
- HNRNPDL | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV99787192; called by muse, mutect2, varscan2
- HRH2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs766094225, COSV99199835; called by muse, mutect2, varscan2
- HSP90AA1 | c.1257del p.K419Nfs*3 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs1566718990; called by mutect2, pindel, varscan2
- HSPG2 | c.6706G>A p.E2236K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762159760, COSV65970087; called by mutect2, varscan2
- HTT | c.5108C>T p.P1703L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs775722498, COSV61856843; called by muse, mutect2, varscan2
- HUWE1 | c.5987G>A p.R1996H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.814); catalogued as rs200650762, COSV53364820; called by muse, mutect2, varscan2
- HUWE1 | c.2972-1G>C p.X991_splice | Splice Site (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99473596; called by muse, mutect2, varscan2
- HYDIN | c.13732G>C p.E4578Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as COSV66642839; called by muse, mutect2, varscan2
- IFT172 | c.3822-1G>T p.X1274_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99563025; called by muse, varscan2
- IFT172 | c.2584del p.D862Tfs*42 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as COSV53131688; called by mutect2, pindel, varscan2
- IGFALS | c.1684G>A p.V562I | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs190570821, COSV99236645; called by muse, mutect2, varscan2
- IL36G | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52079241, COSV99381268; called by muse, mutect2
- ILF3 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99140077; called by muse, mutect2, varscan2
- IMPDH1 | c.1093G>A p.G365S (on ENST00000470772 / NM_001142573.2; = p.G451S on NM_000883.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs756300430, COSV100118767; called by muse, mutect2, varscan2
- IMPG1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs200128845, COSV64058955; called by muse, mutect2, varscan2
- INSR | c.3469C>T p.H1157Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100252976; called by muse, mutect2, varscan2
- INTS2 | c.2998C>G p.L1000V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.969); catalogued as COSV99248573; called by muse, mutect2, varscan2
- ITGA4 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99275582; called by muse, mutect2, varscan2
- ITIH2 | c.2652_2653insA p.A885Sfs*44 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as COSV100623366; called by mutect2, pindel, varscan2
- ITPKC | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as rs1568449971, COSV99648994; called by muse, mutect2
- JAK1 | c.1374C>A p.S458R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.14); catalogued as COSV100691407, COSV100692173, COSV99072541; called by mutect2, varscan2
- KAT14 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV100890101; called by muse, mutect2, varscan2
- KCNJ15 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772620107, COSV60810335; called by muse, mutect2, varscan2
- KIAA1109 | c.8488C>T p.H2830Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1208128339, COSV99169624, COSV99173801; called by muse, mutect2, varscan2
- KIF12 | c.1895G>A p.R632H (on ENST00000640217; = p.R494H on NM_138424.1) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.669); catalogued as rs200697165, COSV65116732; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs753332734; called by mutect2, varscan2
- KIR2DL1 | c.388_390del p.S130del | In Frame Del (DEL) | VAF 32/262 reads (12%) | catalogued as rs762460075; called by mutect2, pindel
- KIT | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV55402906, COSV99854980; called by muse, mutect2, varscan2
- KITLG | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.48); catalogued as COSV99933490; called by muse, mutect2, varscan2
- KLHDC4 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99566629; called by muse, mutect2, varscan2
- KMT2C | c.12673C>T p.R4225* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV51492233; called by muse, mutect2, varscan2
- KRTAP6-3 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 14/96 reads (15%) | PolyPhen probably damaging (0.935); catalogued as COSV101196509; called by muse, mutect2, varscan2
- L1TD1 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1257178921, COSV100776614; called by muse, mutect2, varscan2
- LAMA5 | c.8199C>G p.V2733= | Splice Region (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99441513; called by muse, mutect2, varscan2
- LARP1B | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV99218712; called by muse, mutect2, varscan2
- LCA5L | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99903818; called by muse, mutect2, varscan2
- LCA5L | c.1118G>C p.R373T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99903820; called by muse, mutect2, varscan2
- LCOR | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100603782; called by muse, mutect2, varscan2
- LEXM | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs927900802, COSV100827704; called by muse, mutect2, varscan2
- LGALS1 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.189); catalogued as COSV99313800; called by muse, mutect2, varscan2
- LGALS8 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771204585, COSV53026811; called by muse, mutect2, varscan2
- LIPE | c.865A>G p.R289G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV99734327; called by muse, mutect2, varscan2
- LIX1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99172944; called by muse, mutect2, varscan2
- LRCH3 | c.2110C>T p.H704Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100605199; called by muse, mutect2, varscan2
- LRP2 | c.10196G>A p.R3399Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55549066; called by muse, mutect2, varscan2
- LRP2 | c.8141C>T p.S2714L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs774369141, COSV99789725; called by muse, mutect2, varscan2
- LRPPRC | c.3636A>C p.E1212D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99581207; called by muse, mutect2, varscan2
- LRRC32 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs917928074, COSV99477171; called by muse, mutect2, varscan2
- LRRC37B | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100496431; called by muse, mutect2, varscan2
- LRSAM1 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1317906611, COSV100031788; called by muse, mutect2, varscan2
- LRSAM1 | c.2069G>T p.C690F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100031790; called by muse, varscan2
- LSP1 | c.322del p.Q108Sfs*31 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs752018434; called by pindel, varscan2
- LTB4R | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1325309013, COSV99351045; called by muse, mutect2, varscan2
- MACF1 | c.21326C>T p.A7109V (on ENST00000372915; = p.A5154V on NM_012090.5) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs1306583613, COSV57123524; called by muse, mutect2, varscan2
- MAGEC1 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99596217; called by muse, mutect2
- MAGI3 | c.4132G>C p.E1378Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.063); catalogued as COSV100289966; called by muse, mutect2
- MAL | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as rs775300945, COSV59430769; called by mutect2, varscan2
- MAML3 | c.2721G>T p.Q907H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV101558495; called by muse, mutect2, varscan2
- MAP1B | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57104836; called by muse, mutect2, varscan2
- MAP2K1 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100199214, COSV57235014; called by muse, mutect2, varscan2
- MAP2K5 | c.1075-1G>C p.X359_splice (on ENST00000178640 / NM_145160.3; = p.X349_splice on NM_002757.4) | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99461768; called by muse, mutect2, varscan2
- MAP3K12 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1565887675, COSV99913132; called by muse, mutect2, varscan2
- MAP3K14 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs558318157, COSV60925299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP7D1 | c.2318G>A p.W773* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100294705; called by muse, mutect2
- MAP7D3 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs887874222, COSV100286571; called by mutect2, varscan2
- MASTL | c.2209C>T p.R737* (on ENST00000375940 / NM_001372029.1; = p.R736* on NM_032844.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as rs761508454, COSV60909664; called by muse, mutect2, varscan2
- MB21D2 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV66661939; called by muse, varscan2
- MBD4 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs776001887, COSV99959676; called by muse, mutect2, varscan2
- MBOAT7 | c.1176G>C p.Q392H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99824976; called by muse, mutect2, varscan2
- MCAT | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as rs762000845, COSV99295749; called by muse, mutect2, varscan2
- MEIS1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs780370917, COSV99715634, COSV99715741; called by muse, mutect2, varscan2
- METTL27 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as rs1214985989, COSV99936576; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs780635289; called by mutect2, varscan2
- MGA | c.4517C>A p.S1506Y | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99581030; called by muse, mutect2, varscan2
- MGAT5 | c.1670T>C p.L557P | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.943); catalogued as COSV99924855; called by muse, mutect2, varscan2
- MIA2 | c.1366C>A p.H456N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV99698032; called by muse, mutect2
- MICAL2 | c.2852C>T p.T951M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs765434957, COSV56322217; called by muse, mutect2, varscan2
- MLH1 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as CM159740, COSV51625730, COSV99212611; called by muse, mutect2, varscan2
- MMP12 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100405039; called by muse, mutect2, varscan2
- MN1 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as COSV100180042; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 4/34 reads (12%) | catalogued as rs777649506, COSV53202254; called by pindel, varscan2
- MPP4 | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV59628854; called by muse, mutect2, varscan2
- MROH2B | c.3921G>C p.L1307F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV101270855; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs768684761; called by mutect2, varscan2
- MSRB3 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.364); catalogued as COSV100378165; called by muse, mutect2
- MTDH | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV100292733, COSV60345646; called by muse, mutect2, varscan2
- MTM1 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100080617; called by mutect2, varscan2
- MTOR | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1375320238, COSV100816543; called by mutect2, varscan2
- MTSS1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs184276579, COSV61495397; called by muse, mutect2, varscan2
- MUC1 | c.3188C>T p.S1063F (on ENST00000611571 / NM_001371720.1; = p.S74F on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100104672; called by muse, mutect2, varscan2
- MXD3 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100293707; called by muse, mutect2, varscan2
- MYCL | c.494C>T p.S165L (on ENST00000372816 / NM_001033081.3; = p.S195L on NM_005376.5) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV65694024; called by muse, mutect2, varscan2
- MYO15A | c.5596C>A p.L1866M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99233913; called by muse, mutect2, varscan2
- MYO5A | c.3323C>A p.P1108H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100697992; called by muse, mutect2, varscan2
- MYO6 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100889396; called by muse, mutect2
- N4BP2L2 | c.1746G>T p.Q582H (on ENST00000674422; = p.Q153H on NM_033111.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100679220; called by muse, mutect2, varscan2
- NACA | c.513C>T p.V171= | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs534417377, COSV100771535; called by mutect2, varscan2
- NAIF1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs376436007; called by muse, mutect2, varscan2
- NAP1L4 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV101000733; called by muse, mutect2, varscan2
- NBEA | c.5338C>G p.L1780V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.039); catalogued as rs780695198, COSV100082853; called by muse, mutect2, varscan2
- NCK2 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370241867; called by muse, mutect2, varscan2
- NCOR1 | c.3144del p.K1048Nfs*5 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as rs767736595; called by mutect2, pindel, varscan2
- NCOR2 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); catalogued as rs748412865, COSV100657735; called by muse, mutect2, varscan2
- NDUFS2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99248402; called by muse, mutect2, varscan2
- NF2 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100099043; called by muse, mutect2, varscan2
- NFATC2 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs377351725; called by muse, mutect2
- NFXL1 | c.1634C>A p.T545K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100216964; called by muse, mutect2
- NHSL2 | c.1923del p.K641Nfs*53 (on ENST00000510661; = p.K1007Nfs*53 on NM_001013627.2) | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs755845942; called by mutect2, varscan2
- NIBAN2 | c.1769G>A p.G590D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV100031791; called by muse, mutect2, varscan2
- NLRX1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV52702901, COSV99424692; called by muse, mutect2, varscan2
- NOBOX | c.1322dup p.L442Tfs*35 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs753934412; called by mutect2, varscan2
- NOD2 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV100318787; called by muse, mutect2, varscan2
- NSD1 | c.5804G>T p.C1935F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV100729681; called by muse, mutect2, varscan2
- NSD2 | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs776114283, COSV100373691; called by muse, mutect2, varscan2
- NT5C1A | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.315); catalogued as COSV99348610; called by muse, mutect2
- NUF2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as COSV99616752; called by muse, mutect2
- NUP155 | c.1100G>T p.R367M (on ENST00000231498 / NM_153485.3; = p.R308M on NM_004298.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99194088; called by muse, mutect2, varscan2
- NXPH3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.809); catalogued as rs758345082, COSV60872795; called by muse, mutect2, varscan2
- OBSCN | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99482427; called by muse, mutect2, varscan2
- OR11H1 | c.284del p.N95Tfs*25 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs751979140; called by mutect2, varscan2
- OR1Q1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV52917499, COSV99939330; called by muse, mutect2, varscan2
- OR3A3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs1408026686, COSV99351491; called by muse, mutect2, varscan2
- ORC6 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99530953; called by muse, mutect2, varscan2
- OSBPL8 | c.354del p.E119Nfs*37 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs1565866961, COSV53879345; called by mutect2, pindel, varscan2
- PAK4 | c.1542del p.Y515Tfs*10 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs769136911; called by mutect2, pindel, varscan2
- PAPLN | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV53716913; called by muse, mutect2, varscan2
- PARP3 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs1267960887, COSV51754387; called by muse, mutect2, varscan2
- PARP4 | c.459A>T p.K153N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101131902; called by muse, mutect2, varscan2
- PARP4 | c.458A>T p.K153I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV101131903; called by muse, mutect2, varscan2
- PASD1 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV100949511; called by mutect2, varscan2
- PAXBP1 | c.2422A>G p.I808V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV99269446; called by muse, mutect2
- PCDHA13 | c.1334T>C p.V445A | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99167914; called by muse, mutect2, varscan2
- PCDHA2 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs782528536, COSV65367538, COSV65367637; called by muse, mutect2, varscan2
- PCDHA3 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV63540376; called by muse, mutect2, varscan2
- PCDHA5 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1307861296, COSV65349683; called by muse, mutect2, varscan2
- PCDHB13 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 10/176 reads (6%) | catalogued as COSV99507617; called by muse, mutect2
- PCDHGB6 | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.158); catalogued as rs1379621758, COSV99543661; called by muse, mutect2, varscan2
- PCLO | c.713C>G p.S238* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100435887; called by mutect2, varscan2
- PCLO | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100435893; called by mutect2, varscan2
- PDCD4 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375978756, COSV99701258; called by mutect2, varscan2
- PDE10A | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as rs1403420962, COSV63091276; called by muse, mutect2, varscan2
- PDLIM5 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as COSV100524184; called by mutect2, varscan2
- PGK1 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100965360; called by muse, mutect2, varscan2
- PHF11 | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.307); catalogued as COSV51633258, COSV99319647; called by muse, mutect2
- PITPNM1 | c.3142G>A p.A1048T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868782064, COSV99653783; called by mutect2, varscan2
- PJA1 | c.1028G>A p.R343H (on ENST00000361478 / NM_145119.4; = p.R155H on NM_022368.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.379); catalogued as rs140630019, COSV100824619, COSV64053358; called by muse, mutect2, varscan2
- PLA2G4F | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100529432; called by muse, mutect2, varscan2
- PLAG1 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV100388130; called by muse, mutect2, varscan2
- PLD2 | c.2577G>T p.Q859H | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV99562596; called by muse, mutect2
- PLK4 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.89); catalogued as COSV99584852; called by muse, mutect2
- PLXNA2 | c.4865-1G>T p.X1622_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100885694; called by muse, mutect2, varscan2
- PLXNB3 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs782172672, COSV100737745; called by muse, mutect2, varscan2
- PNISR | c.281G>T p.W94L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV100984404; called by muse, mutect2, varscan2
- PNLIPRP3 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100982567; called by muse, mutect2, varscan2
- PNMA8A | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100562400; called by muse, mutect2, varscan2
- POLRMT | c.2411G>A p.G804D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99242184; called by muse, mutect2
- POM121C | c.827C>T p.P276L (on ENST00000607367; = p.P34L on NM_001099415.3) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs781917934, COSV99992941; called by muse, mutect2, varscan2
- PON1 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99732506; called by muse, mutect2, varscan2
- PPIG | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV99644805; called by mutect2, varscan2
- PPIP5K2 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.676); catalogued as rs369404751; called by muse, mutect2, varscan2
- PPM1F | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV99601629; called by muse, mutect2
- PPP1R3A | c.1428del p.N476Kfs*4 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs1056475720, COSV52881818; called by mutect2, varscan2
- PPP1R9B | c.1096dup p.V366Gfs*12 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs1259994219; called by mutect2, pindel, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as rs540232176; called by mutect2, varscan2
- PPP4R3A | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100466343; called by muse, mutect2, varscan2
- PPP6R2 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142606064; called by muse, mutect2, varscan2
- PREPL | c.2156A>G p.E719G | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV99576378; called by muse, mutect2, varscan2
- PRG4 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs755333400, COSV100825887; called by muse, mutect2, varscan2
- PRPH | c.1058del p.G353Afs*16 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as rs765336123, COSV57678836, COSV57679119; called by pindel, varscan2
- PRR22 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV100288401; called by muse, varscan2
- PSG9 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52488469, COSV99392489; called by muse, mutect2, varscan2
- PSMC2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99485418; called by muse, mutect2, varscan2
- PTPN6 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201976465, COSV100017217; called by muse, mutect2, varscan2
- PTPRF | c.4223C>T p.A1408V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100741100; called by mutect2, varscan2
- PTPRS | c.5296C>T p.R1766C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157608522, COSV53620465; called by muse, mutect2, varscan2
- PXMP2 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746666562, COSV100443606, COSV58096846; called by muse, mutect2, varscan2
- RAD54L2 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV99621661; called by muse, mutect2, varscan2
- RAPSN | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778113748, COSV100100331; called by muse, mutect2, varscan2
- RBM3 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV63202908; called by muse, mutect2
- RBPJ | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100623698, COSV60754549; called by muse, mutect2, varscan2
- RELN | c.9922T>C p.Y3308H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV100634470; called by muse, mutect2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as rs759247453; called by mutect2, varscan2
- REXO1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368328980; called by muse, mutect2, varscan2
- RFC1 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100567921; called by mutect2, varscan2
- RILPL1 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs200694798; called by muse, mutect2, varscan2
- RIN3 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as rs748704510, COSV53653445; called by mutect2, varscan2
- RNF113A | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.97); catalogued as COSV65097112; called by muse, mutect2, varscan2
- RNF123 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.378); catalogued as COSV100571044; called by muse, mutect2, varscan2
- RPAP1 | c.3757G>A p.V1253M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs143725774; called by muse, mutect2, varscan2
- RPL7L1 | c.270G>C p.L90F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV100491783; called by muse, mutect2, varscan2
- RPS19 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as CM108600, COSV99702615; called by muse, mutect2, varscan2
- RPTOR | c.913A>G p.R305G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100156905; called by muse, mutect2, varscan2
- RTEL1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs368311594; called by muse, mutect2, varscan2
- RTKN | c.1667G>A p.R556H (on ENST00000272430 / NM_001015055.2; = p.R543H on NM_033046.2) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs201347198, COSV51967724; called by muse, mutect2, varscan2
- RXFP3 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs760175538, COSV57505486; called by muse, mutect2, varscan2
- SAMD14 | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1314697863, COSV50303678; called by muse, mutect2
- SAMD4B | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs1353739880, COSV100080577; called by muse, varscan2
- SCAF1 | c.1951G>A p.G651S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs1346335060, COSV100862246; called by muse, mutect2, varscan2
- SCAF1 | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.832); catalogued as COSV100862248; called by muse, varscan2
- SCN10A | c.2864G>A p.S955N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.243); catalogued as COSV101479487; called by muse, mutect2, varscan2
- SCO2 | c.800G>C p.*267Sext*? | Nonstop Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as rs985148465, COSV99329722; called by muse, mutect2, varscan2
- SDCCAG8 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV100654492; called by muse, mutect2
- SEL1L2 | c.1571-1G>A p.X524_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as rs1050456321, COSV99533708; called by muse, mutect2, varscan2
- SEPHS1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs955621821, COSV59259083; called by muse, mutect2, varscan2
- SEPTIN11 | c.833T>A p.I278N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99346575; called by muse, mutect2, varscan2
- SFXN5 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs373206510; called by muse, mutect2, varscan2
- SH2D4B | c.973G>A p.A325T (on ENST00000646907; = p.A324T on NM_207372.2) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs527861608, COSV57892410; called by mutect2, varscan2
- SHOX2 | c.380C>T p.A127V (on ENST00000441443 / NM_006884.3; = p.A151V on NM_003030.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs747319392, COSV67463867; called by muse, varscan2
- SHPRH | c.3061C>T p.R1021* (on ENST00000275233 / NM_001042683.3; = p.R1030* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99262501; called by muse, mutect2, varscan2
- SLA | c.824A>T p.E275V (on ENST00000338087 / NM_001045556.3; = p.E315V on NM_006748.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV99602400; called by muse, mutect2, varscan2
- SLAMF6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.216); catalogued as rs758426351, COSV100924891, COSV100924923; called by muse, mutect2, varscan2
- SLC11A1 | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV99262357; called by muse, mutect2, varscan2
- SLC14A2 | c.1957C>G p.L653V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV54910730, COSV99675959; called by muse, mutect2, varscan2
- SLC17A2 | c.361del p.M121Cfs*7 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs770669846; called by mutect2, varscan2
- SLC17A8 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60121892; called by muse, mutect2, varscan2
- SLC29A4 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs774254094, COSV99786895; called by muse, mutect2, varscan2
- SLC5A6 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV100143483; called by muse, mutect2, varscan2
- SLC6A15 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1399448465, COSV99881331; called by muse, mutect2
- SLC7A11 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760898836, COSV99763394; called by muse, mutect2, varscan2
- SMAD1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.449); catalogued as COSV57471241; called by muse, mutect2, varscan2
- SMAP1 | c.925T>C p.Y309H (on ENST00000370455 / NM_001044305.3; = p.Y282H on NM_021940.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100017279; called by muse, mutect2, varscan2
- SMARCAD1 | c.2833A>C p.I945L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100759007; called by muse, mutect2
- SMARCC2 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1292823810, COSV57217320; called by muse, mutect2, varscan2
- SMC2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as rs751500565, COSV53961142; called by muse, mutect2, varscan2
- SNX2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV101075798; called by muse, mutect2, varscan2
- SNX20 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV100319294; called by muse, mutect2, varscan2
- SOGA3 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV64105368; called by muse, mutect2
- SORCS2 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs745591535, COSV100213411; called by muse, mutect2, varscan2
- SOX5 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs759171095, COSV100507662; called by muse, mutect2, varscan2
- SP110 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs200559722; called by muse, mutect2, varscan2
- SPATA2 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs201940082, COSV99192911; called by muse, mutect2, varscan2
- SPOPL | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs142534399, COSV54511514; called by muse, mutect2
- SPTBN4 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58959511; called by muse, mutect2, varscan2
- SRPX2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100884048, COSV65933132; called by muse, mutect2, varscan2
- SRSF4 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100861427; called by muse, mutect2, varscan2
- SSR3 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs758900330, COSV54020559; called by muse, mutect2, varscan2
- ST18 | c.1862del p.N621Ifs*10 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs1563701552; called by mutect2, varscan2
- ST6GAL1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | PolyPhen benign (0.036); catalogued as COSV99399423; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.827del p.G276Vfs*20 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as COSV60336092; called by mutect2, pindel, varscan2
- ST8SIA5 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | PolyPhen benign (0.006); catalogued as COSV100164868; called by muse, mutect2, varscan2
- STAB2 | c.7421C>A p.A2474D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV101186191; called by muse, mutect2, varscan2
- STAG2 | c.877T>C p.F293L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99494830; called by muse, mutect2, varscan2
- STAM2 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99813265; called by muse, mutect2, varscan2
- SULT1A2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs773661297, COSV100187294; called by muse, mutect2, varscan2
- SYNE1 | c.5716G>T p.E1906* (on ENST00000367255 / NM_182961.4; = p.E1913* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99574082; called by muse, mutect2
- TAB1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs375269432; called by muse, mutect2, varscan2
- TAS2R50 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as COSV101115320; called by muse, mutect2, varscan2
- TBC1D1 | c.3178G>C p.E1060Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99791880; called by muse, mutect2, varscan2
- TBC1D10B | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99977177; called by muse, mutect2, varscan2
- TBC1D25 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100952201; called by muse, mutect2, varscan2
- TBX2 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as COSV99539052; called by muse, mutect2, varscan2
- TENT4B | c.1763C>T p.S588L (on ENST00000561678 / NM_001365323.2; = p.S573L on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100666136; called by muse, mutect2, varscan2
- TET1 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV101018678; called by muse, mutect2, varscan2
- TFDP1 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100945991; called by muse, mutect2, varscan2
- TFEB | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV100026390; called by muse, mutect2, varscan2
- TFRC | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs764730449, COSV100786570, COSV64057113; called by muse, mutect2, varscan2
- TGFBI | c.1613del p.T538Kfs*32 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as CM022470; called by mutect2, pindel, varscan2
- THAP7 | c.343del p.A115Lfs*156 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as COSV53145439; called by mutect2, varscan2
- THBS3 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs753048328, COSV57428329; called by muse, mutect2, varscan2
- TIMM17B | c.482del p.P161Rfs*40 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | catalogued as COSV54430556, COSV99504193; called by mutect2, pindel, varscan2
- TLL2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs753483261, COSV100780389; called by muse, mutect2, varscan2
- TMEM100 | c.296del p.L99Yfs*2 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as rs894486999; called by mutect2, pindel, varscan2
- TMEM131L | c.2617C>T p.L873F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99547911; called by muse, mutect2, varscan2
- TMEM132D | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV101398472; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs747222326; called by mutect2, varscan2
- TNN | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV99512618; called by muse, mutect2
- TPBG | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV100869799; called by mutect2, varscan2
- TPSG1 | c.672dup p.P225Afs*20 | Frame Shift Ins (INS) | VAF 17/63 reads (27%) | catalogued as rs767679644; called by mutect2, pindel, varscan2
- TRAK1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.522); catalogued as rs537037086, COSV100565789; called by muse, mutect2, varscan2
- TRAP1 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.196); catalogued as COSV99893785; called by muse, mutect2, varscan2
- TRH | c.319dup p.A107Gfs*16 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | catalogued as rs770451471; called by mutect2, varscan2
- TRIM42 | c.1667G>A p.C556Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53887753, COSV53887844; called by mutect2, varscan2
- TRIT1 | c.1226A>T p.E409V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100381652; called by muse, mutect2, varscan2
- TRPA1 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100084855; called by muse, mutect2, varscan2
- TRPC1 | c.2250G>T p.M750I (on ENST00000476941 / NM_001251845.2; = p.M716I on NM_003304.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.258); catalogued as COSV99859179; called by muse, varscan2
- TRRAP | c.11507A>C p.N3836T (on ENST00000359863 / NM_001244580.1; = p.N3807T on NM_003496.3) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV100705474; called by muse, mutect2, varscan2
- TSC2 | c.4168G>T p.E1390* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs397515033, CM052383, COSV99238756; ClinVar: not provided; called by muse, mutect2, varscan2
- TSGA10IP | c.194A>G p.Q65R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101598425; called by muse, mutect2, varscan2
- TSSK6 | c.27A>T p.E9D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99389209; called by muse, mutect2, varscan2
- TTC13 | c.1339del p.T448Rfs*25 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs867367503; called by mutect2, pindel, varscan2
- TTN | c.96556C>T p.R32186C (on ENST00000591111; = p.R24762C on NM_003319.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | PolyPhen probably damaging (0.909); catalogued as rs372067498, COSV59906084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.90031G>T p.G30011* (on ENST00000591111; = p.G22587* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100623596, COSV60230612; called by muse, mutect2, varscan2
- TTN | c.79293A>G p.I26431M (on ENST00000591111; = p.I19007M on NM_003319.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | PolyPhen benign (0.421); catalogued as COSV100623597; called by muse, mutect2, varscan2
- TTN | c.79009G>T p.E26337* (on ENST00000591111; = p.E18913* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100623601; called by muse, mutect2
- TTN | c.14872G>T p.G4958* (on ENST00000591111; = p.G4031* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100623603, COSV60244311; called by muse, mutect2, varscan2
- UBE2U | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV64280596, COSV64281587; called by muse, mutect2, varscan2
- UBTF | c.1551G>C p.M517I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100256074; called by muse, mutect2, varscan2
- UBTF | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100256076; called by muse, mutect2, varscan2
- UGT2B11 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1246076192, COSV101485278; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs767420916; called by mutect2, varscan2
- VASN | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as rs1245091799, COSV99228000; called by muse, mutect2, varscan2
- VAV3 | c.471_473del p.E157del | In Frame Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1362300566; called by pindel, varscan2
- VEPH1 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100747864; called by mutect2, varscan2
- VPS13B | c.6709G>A p.D2237N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV62139938; called by muse, mutect2, varscan2
- VPS33A | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.757); catalogued as rs186215132, COSV57357418; called by muse, mutect2, varscan2
- VPS36 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100955263; called by muse, mutect2, varscan2
- VPS72 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1454786020, COSV54860544; called by muse, mutect2, varscan2
- VWA3A | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs750392134, COSV55389775, COSV55390999; called by muse, mutect2, varscan2
- WDFY3 | c.7666C>G p.L2556V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99884938; called by muse, mutect2, varscan2
- WDR83OS | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV99663977; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- WSCD1 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100496729; called by muse, mutect2, varscan2
- WWC1 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99515639; called by muse, mutect2, varscan2
- XAB2 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV100222079; called by muse, mutect2, varscan2
- XPO6 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs145368246, COSV100484753; called by mutect2, varscan2
- YEATS2 | c.3157A>C p.S1053R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100528170; called by muse, mutect2, varscan2
- YIPF2 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV99450257; called by muse, mutect2, varscan2
- YPEL1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100256424; called by mutect2, varscan2
- ZBTB10 | c.2352G>C p.K784N (on ENST00000430430; = p.K760N on NM_023929.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV100990272; called by muse, mutect2, varscan2
- ZC3H12C | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99585228; called by muse, mutect2, varscan2
- ZCCHC8 | c.1957G>C p.A653P | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100288784; called by muse, mutect2, varscan2
- ZFR | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.034); catalogued as COSV99416337; called by muse, mutect2
- ZNF148 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV100642162; called by muse, mutect2, varscan2
- ZNF157 | c.598A>C p.S200R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100998519; called by muse, mutect2, varscan2
- ZNF184 | c.453G>C p.E151D | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99279930; called by muse, mutect2, varscan2
- ZNF211 | c.1477A>G p.K493E (on ENST00000347302 / NM_198855.4; = p.K506E on NM_006385.5) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV99560402; called by muse, mutect2, varscan2
- ZNF236 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1382268069, COSV99470953; called by muse, mutect2, varscan2
- ZNF236 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868369821, COSV53485531; called by muse, mutect2, varscan2
- ZNF43 | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV100731917; called by muse, mutect2, varscan2
- ZNF480 | c.1342A>G p.I448V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV100574286; called by muse, mutect2, varscan2
- ZNF500 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs139150092; called by mutect2, varscan2
- ZNF558 | c.590T>A p.I197N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100038010; called by muse, mutect2, varscan2
- ZNF578 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.953); catalogued as COSV101405100; called by muse, mutect2, varscan2
- ZNF787 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99555591; called by muse, mutect2, varscan2
- ZNF829 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV101199697, COSV66987050; called by muse, mutect2, varscan2
- ZNF875 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs201823175, COSV100183499; called by muse, mutect2, varscan2
- ZSWIM8 | c.2183A>G p.D728G | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101290082; called by muse, mutect2, varscan2
- ABL2 | c.824C>T p.S275F (on ENST00000502732 / NM_007314.4; = p.S260F on NM_005158.5) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ALK | c.1435del p.Y479Tfs*28 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.2481dup p.E828Rfs*4 (on ENST00000611781; = p.E772Rfs*4 on NM_052997.2) | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- AOC3 | c.1968del p.T657Lfs*22 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, varscan2
- ARHGAP29 | c.1839_1840dup p.K614Tfs*6 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- BICC1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.037); called by muse, varscan2
- CAMSAP2 | c.504del p.Q169Kfs*17 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- CDKN1C | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- CFAP74 | c.1521del p.R508Vfs*33 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- CILP | c.841_842del p.K281Vfs*12 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- COL22A1 | c.4328del p.P1443Qfs*12 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- COL3A1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- CSNK1G2 | c.115del p.V39Sfs*2 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- CTR9 | c.2937del p.K980Nfs*25 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- CYP2A6 | c.726dup p.G243Rfs*27 | Frame Shift Ins (INS) | VAF 33/126 reads (26%) | called by mutect2, pindel, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- DNAJC16 | c.35dup p.I14Dfs*16 | Frame Shift Ins (INS) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.210_211del p.Y71Pfs*38 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by pindel, varscan2
- ENTPD7 | c.1267del p.Y423Ifs*33 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- EPHA2 | c.719del p.G240Vfs*153 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- FNTB | c.1003del p.L335Cfs*6 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- GAS2L2 | c.1642T>C p.S548P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR22 | c.1058del p.L353* | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel
- GPR75 | c.194T>C p.L65S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.28); called by muse, mutect2
- GPRASP1 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2
- HMMR | c.379del p.T127Hfs*17 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- HNRNPAB | c.455del p.P152Rfs*2 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- HSD11B1L | c.31del p.A11Pfs*24 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- ITGA4 | c.1843del p.T615Qfs*2 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- KDM5B | c.906del p.A303Pfs*37 | Frame Shift Del (DEL) | VAF 13/112 reads (12%) | called by mutect2, pindel
- LATS2 | c.2741del p.L914Wfs*10 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- LMTK3 | c.2750del p.P917Qfs*3 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- MAP3K20 | c.665del p.N222Tfs*4 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- MUC5B | c.5588del p.T1863Kfs*68 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- NAF1 | c.1415del p.P472Lfs*25 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- NCAN | c.1359del p.S454Afs*33 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- NIBAN3 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NOTCH3 | c.2160_2161dup p.E721Vfs*140 | Frame Shift Ins (INS) | VAF 9/65 reads (14%) | called by mutect2, varscan2
- OR10G7 | c.308del p.F103Sfs*32 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- OR11H4 | c.885del p.F295Lfs*4 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- PLEKHG2 | c.139del p.R47Efs*9 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- POLR1A | c.3054del p.Y1019Mfs*28 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- POLR2C | c.644_645del p.E215Vfs*6 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- POM121L12 | c.558dup p.K187Qfs*5 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- RETREG3 | c.246dup p.A83Cfs*22 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- SAE1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SAFB | c.2399del p.G800Afs*8 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- SEMA4A | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- SIRT5 | c.141dup p.A48Cfs*15 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by pindel, varscan2
- THBS4 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2
- THEM5 | c.461del p.P154Qfs*12 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- TMEM145 | c.123C>T p.D41= | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TMEM223 | c.212dup p.V72Gfs*91 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel
- TRAP1 | c.1509del p.N504Tfs*14 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- TRPC1 | c.2199del p.V734* (on ENST00000476941 / NM_001251845.2; = p.V700* on NM_003304.4) | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by pindel, varscan2
- TSKS | c.344del p.P115Lfs*19 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- USP21 | c.405dup p.G136Wfs*12 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- USP21 | c.1426del p.S476Vfs*3 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- USP9X | c.5634del p.H1879Ifs*27 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- ZDHHC19 | c.875del p.P292Qfs*61 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- ZFYVE9 | c.963del p.E322Sfs*68 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, pindel, varscan2
- ZNF107 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- ZNF791 | c.1164del p.K388Nfs*10 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- AASS | c.363C>G p.G121= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- ABHD2 | c.690C>T p.C230= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs763642629, COSV61773142; called by muse, mutect2, varscan2
- ACOX3 | c.2004C>T p.G668= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs777291758, COSV62711932; called by muse, mutect2, varscan2
- ADAM32 | c.309A>T p.G103= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101165454; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4332G>A p.T1444= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs566582553, COSV65876738; called by muse, mutect2, varscan2
- AGAP3 | c.630C>T p.I210= (on ENST00000622464; = p.I246= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1395917213, COSV58994432; called by muse, mutect2, varscan2
- ALOX15 | c.1224C>G p.V408= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99541636; called by muse, varscan2
- AMER1 | c.3042G>A p.G1014= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV100366834; called by muse, mutect2
- AMPD3 | c.1755G>A p.P585= (on ENST00000396553 / NM_001025389.2; = p.P594= on NM_000480.3) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs774345890, COSV101158225; called by muse, mutect2, varscan2
- ANGPTL4 | c.885C>T p.G295= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs764437255, COSV100035227; called by muse, mutect2, varscan2
- ANKRD24 | c.1491C>T p.D497= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1487048551, COSV99517963; called by muse, mutect2, varscan2
- ANKRD34A | c.1005C>T p.R335= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs782074916, COSV100041362; called by muse, mutect2, varscan2
- ANKRD34A | c.480C>G p.L160= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100041360; called by muse, mutect2, varscan2
- AOC1 | c.687G>A p.G229= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100710912; called by muse, mutect2
- AP3B2 | c.465G>A p.S155= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99916834; called by muse, mutect2, varscan2
- APOB | c.6837G>A p.Q2279= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs747345046, COSV99267104; called by muse, mutect2, varscan2
- ARAF | c.1161C>A p.G387= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99283383; called by muse, mutect2, varscan2
- ARF1 | c.435G>A p.L145= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99683300; called by muse, mutect2, varscan2
- ARFGEF3 | c.489C>T p.L163= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1173919233, COSV99294373; called by muse, mutect2, varscan2
- ARHGEF1 | c.912C>T p.G304= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as rs782392629, COSV100529143; called by muse, mutect2
- ATIC | c.525C>A p.A175= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99378062; called by muse, mutect2
- BRWD3 | c.5391C>T p.L1797= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100956365; called by muse, mutect2, varscan2
- C9orf40 | c.312A>G p.V104= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1375294180, COSV100964983; called by mutect2, varscan2
- CACNA1F | c.2529A>G p.V843= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100545222; called by muse, mutect2
- CACNA2D4 | c.552C>T p.G184= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99765364; called by mutect2, varscan2
- CBLN3 | c.318C>T p.G106= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs1217283907, COSV52160561; called by muse, mutect2
- CBX2 | c.270C>T p.S90= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV53970096; called by muse, mutect2, varscan2
- CDK16 | c.1350G>T p.G450= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV99331896; called by muse, mutect2, varscan2
- CEBPG | c.168G>A p.S56= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs776046712, COSV52287083; called by muse, mutect2, varscan2
- CELSR2 | c.5742G>A p.R1914= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99604499; called by muse, mutect2, varscan2
- CERS6 | c.141T>C p.C47= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99987460; called by muse, mutect2, varscan2
- CHD9 | c.2820G>A p.G940= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99529543; called by muse, mutect2, varscan2
- CHST1 | c.1009C>A p.R337= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100346427, COSV57324244; called by muse, mutect2, varscan2
- CNTN6 | c.708T>C p.T236= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs374989978, COSV63175697; called by muse, mutect2, varscan2
- COL23A1 | c.615C>T p.G205= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV101179492; called by muse, mutect2, varscan2
- COL27A1 | c.3669G>A p.L1223= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as rs745526511, COSV61925122; called by muse, mutect2, varscan2
- COL4A2 | c.891C>T p.I297= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV100847438; called by muse, mutect2, varscan2
- DCP2 | c.777G>A p.T259= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs777634554, COSV66617458; called by mutect2, varscan2
- DCT | c.558G>A p.V186= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1387662456, COSV100986270; called by muse, mutect2, varscan2
- DDI2 | c.144C>A p.V48= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100197840; called by muse, mutect2
- DIP2A | c.3726C>T p.R1242= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1464518717, COSV59473394; called by muse, mutect2, varscan2
- DNAH17 | c.5004C>G p.L1668= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV101103109; called by muse, mutect2, varscan2
- DNASE2 | c.720C>T p.S240= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs774148521, COSV52245625, COSV99262120; called by muse, mutect2, varscan2
- DSPP | c.1857C>T p.S619= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1476610450; called by muse, mutect2, varscan2
- EAF2 | c.297G>A p.R99= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV99877596; called by muse, mutect2, varscan2
- EFCAB5 | c.879C>T p.F293= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs368209807, COSV104413761; called by muse, mutect2, varscan2
- ELOA2 | c.1818G>A p.E606= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99797508; called by muse, mutect2, varscan2
- EML1 | c.309A>G p.L103= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs961556397, COSV99215425; called by muse, mutect2, varscan2
- ESYT1 | c.2640C>G p.L880= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV57273013, COSV99920183; called by muse, mutect2, varscan2
- ETV1 | c.564C>T p.R188= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs948240877, COSV99624223; called by muse, mutect2, varscan2
- FAT3 | c.12897C>T p.C4299= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99963057; called by muse, varscan2
- FBN1 | c.3423G>A p.P1141= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs140396599; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by mutect2, varscan2
- FCGBP | c.6498G>A p.S2166= | Silent (SNP) | VAF 28/251 reads (11%) | catalogued as rs948159558, COSV99663473; called by muse, mutect2, varscan2
- FOLH1 | c.834T>G p.A278= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV99923648; called by muse, mutect2
- FOXD4L1 | c.228C>T p.G76= | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as rs750697258, COSV52075747; called by muse, mutect2, varscan2
- FOXM1 | c.1881G>A p.T627= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs374998139; ClinVar: likely benign; called by mutect2, varscan2
- GAD2 | c.1212C>T p.C404= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99393791; called by muse, mutect2, varscan2
- GALNT18 | c.1368C>T p.S456= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs140408899; called by muse, mutect2, varscan2
- GCFC2 | c.744C>T p.G248= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV100319663; called by muse, mutect2, varscan2
- GFOD1 | c.900G>A p.S300= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs974380914, COSV64954204; called by mutect2, varscan2
- GON4L | c.2769T>C p.S923= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99675298; called by muse, mutect2, varscan2
- GPRIN1 | c.2943G>A p.K981= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99992005; called by mutect2, varscan2
- GTF2H4 | c.702C>G p.L234= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99462085; called by muse, mutect2, varscan2
- GTF3C1 | c.4473C>T p.N1491= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1381920785, COSV100649625; called by muse, mutect2, varscan2
- H2AJ | c.297C>T p.G99= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs1238595144, COSV100797669; called by muse, mutect2, varscan2
- HELB | c.3078T>C p.D1026= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99922118; called by muse, mutect2
- HMCN1 | c.1932C>A p.A644= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99633557; called by muse, mutect2, varscan2
- HMCN1 | c.8733G>A p.Q2911= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs757150387, COSV99633564; called by muse, mutect2, varscan2
- IFNA10 | c.228C>A p.A76= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as COSV99497561; called by muse, mutect2
- IFT172 | c.3411C>G p.L1137= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99563027; called by muse, mutect2, varscan2
- INTS2 | c.1392G>A p.A464= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs897048190, COSV99248575; called by muse, mutect2, varscan2
- IPP | c.1740C>T p.G580= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs780790120, COSV100739670; called by muse, mutect2, varscan2
- IQSEC2 | c.2670C>T p.L890= (on ENST00000642864 / NM_001111125.3; = p.L685= on NM_015075.2) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100945039; called by muse, mutect2, varscan2
- IRF2BP1 | c.418C>T p.L140= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1193392287, COSV100138966; called by muse, mutect2, varscan2
- IRS2 | c.3513C>T p.R1171= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs542315127, COSV101019308; called by muse, mutect2, varscan2
- ITGB4 | c.612G>A p.K204= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV52334522, COSV99564511; called by muse, varscan2
- ITPRIPL1 | c.1578C>T p.P526= (on ENST00000439118 / NM_001008949.3; = p.P534= on NM_178495.6) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100742229; called by muse, mutect2, varscan2
- KCNH1 | c.168C>T p.H56= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1174368310, COSV99660604; called by muse, mutect2, varscan2
- KCNH2 | c.1185C>A p.I395= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100060731; called by muse, mutect2, varscan2
- KCNH6 | c.945C>T p.I315= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs754609560, COSV59000489; called by muse, mutect2, varscan2
- KCTD5 | c.48C>T p.I16= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV100069673; called by muse, mutect2, varscan2
- KLF11 | c.957T>G p.A319= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100007854; called by muse, mutect2, varscan2
- KRT24 | c.1521G>A p.V507= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs750536956, COSV99232127; called by muse, mutect2, varscan2
- KRT6A | c.1503T>C p.S501= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs567110834, COSV100417112; called by muse, mutect2, varscan2
- LAMA5 | c.1422G>A p.T474= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99441514; called by muse, mutect2
- LEP | c.472C>T p.L158= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV58241173; called by muse, mutect2, varscan2
- LHX6 | c.189G>A p.P63= (on ENST00000373755 / NM_001242334.2; = p.P92= on NM_014368.5) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1294979671, COSV100493558; called by muse, mutect2, varscan2
- LY6E | c.192C>T p.G64= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99465147; called by muse, mutect2
- MAPK10 | c.30C>T p.F10= (on ENST00000359221 / NM_001351625.2; = p.F48= on NM_002753.5) | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV100175122; called by muse, mutect2, varscan2
- MAPKAPK2 | c.372C>T p.Y124= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs782726803, COSV54314372; called by muse, mutect2, varscan2
- MC2R | c.549G>A p.P183= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs200075322, COSV59617856; called by muse, mutect2
- MLNR | c.534C>T p.G178= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1195497119, COSV54532023; called by muse, mutect2
- MMP16 | c.855C>T p.G285= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV54161754; called by muse, mutect2, varscan2
- MMP17 | c.612C>T p.G204= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs778573423, COSV62178861; called by muse, mutect2, varscan2
- MMUT | c.1302C>A p.L434= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as CD060618, COSV51273022, COSV99222491; called by muse, mutect2, varscan2
- MORC2 | c.1344G>A p.A448= (on ENST00000397641 / NM_001303256.3; = p.A386= on NM_014941.3) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs781067804, COSV99310236; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.40305C>T p.L13435= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs776673653, COSV101110014, COSV66694562; called by muse, mutect2, varscan2
- MUC6 | c.4197G>A p.T1399= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs749227430, COSV70149590; called by muse, mutect2, varscan2
- MYO1B | c.2490C>T p.R830= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs770052311, COSV100269751; called by mutect2, varscan2
- MYT1L | c.1272C>T p.F424= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs553083381, COSV67708347, COSV67709367; called by muse, mutect2, varscan2
- NAV1 | c.282C>G p.L94= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99819414; called by muse, mutect2, varscan2
- NLGN2 | c.2031C>T p.S677= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs759648194, COSV57210096; called by muse, mutect2, varscan2
- NLRP12 | c.2721C>T p.G907= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100145628, COSV60745643; called by muse, mutect2, varscan2
- NOMO1 | c.2631C>T p.G877= | Silent (SNP) | VAF 10/137 reads (7%) | catalogued as rs140931654; called by muse, mutect2
- NOS2 | c.3246C>T p.C1082= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs201378393, COSV100569820; called by muse, varscan2
- NRK | c.1917G>C p.L639= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99688750, COSV99689500; called by muse, mutect2, varscan2
- ONECUT1 | c.480C>T p.S160= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV59947746; called by muse, mutect2, varscan2
- OR1N2 | c.196C>T p.L66= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs377757188; called by muse, mutect2, varscan2
- OR1Q1 | c.576C>T p.T192= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1180028672, COSV99939331; called by muse, mutect2, varscan2
- OTULIN | c.993G>A p.T331= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99419946; called by mutect2, varscan2
- PCDH17 | c.1194C>T p.G398= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100931817; called by muse, mutect2, varscan2
- PCDHGA10 | c.2226G>A p.S742= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs1408496357, COSV53964267; called by muse, mutect2
- PCDHGA4 | c.2052T>C p.P684= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV99543660; called by muse, mutect2, varscan2
- PDIA3 | c.375C>T p.V125= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs1434993304, COSV100295217, COSV55854749; called by muse, mutect2, varscan2
- PEG10 | c.732T>C p.A244= (on ENST00000482108 / NM_001040152.2; = p.A278= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV101509938; called by muse, mutect2, varscan2
- PIGG | c.1215C>T p.G405= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs752657650, COSV99574202; called by muse, mutect2, varscan2
- PIKFYVE | c.1620C>T p.H540= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100011220; called by mutect2, varscan2
- PITPNM3 | c.561C>T p.C187= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs966736382, COSV99338815; called by muse, mutect2, varscan2
- PLXNA1 | c.3726G>A p.T1242= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1198641116, COSV99303104; called by muse, mutect2, varscan2
- PLXNB3 | c.2319G>A p.Q773= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs782381462, COSV100737746, COSV62800520; called by muse, mutect2, varscan2
- PNLIP | c.663G>A p.T221= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs137958300, COSV100981679; called by muse, mutect2, varscan2
- PPL | c.4935C>G p.V1645= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99278441; called by muse, mutect2, varscan2
- PPP1R26 | c.123G>A p.A41= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs368903595; called by muse, mutect2, varscan2
- PPP2R2C | c.1095C>T p.F365= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1351701311, COSV100160790, COSV59447144; called by muse, mutect2, varscan2
- PRAMEF8 | c.930G>A p.K310= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as rs1472418958; called by muse, mutect2
- PRKG1 | c.204G>A p.P68= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100918379; called by muse, mutect2, varscan2
- PRMT7 | c.1992C>T p.G664= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99545918; called by muse, mutect2
- PROC | c.714C>T p.C238= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs141249033; called by mutect2, varscan2
- PTPN6 | c.90G>T p.R30= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs781847446, COSV100017216; called by muse, mutect2, varscan2
- PTPRU | c.3960C>G p.V1320= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs776371235, COSV100113446; called by muse, mutect2, varscan2
- RAPGEFL1 | c.657T>C p.C219= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99229173; called by muse, varscan2
- RASA3 | c.2379G>A p.E793= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100481035; called by muse, mutect2
- RASGRP3 | c.1182G>A p.T394= (on ENST00000402538 / NM_001349975.2; = p.T393= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs199713394; called by muse, mutect2, varscan2
- RBM45 | c.270C>T p.C90= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99617712; called by muse, mutect2, varscan2
- RLF | c.5058T>C p.C1686= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV101035611; called by muse, mutect2, varscan2
- RMI1 | c.957C>A p.A319= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100366418; called by muse, mutect2, varscan2
- RNASEL | c.2223C>T p.C741= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100842630; called by muse, mutect2, varscan2
- RNF10 | c.216C>G p.P72= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100378866; called by muse, mutect2, varscan2
- RUNX1T1 | c.1485G>A p.R495= (on ENST00000265814 / NM_001198628.1; = p.R468= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56153929, COSV99754190; called by muse, mutect2
- RYR2 | c.6081G>A p.G2027= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100772111, COSV63708415; called by muse, mutect2
- SAMD4B | c.1245G>A p.P415= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs759737546, COSV58753936; called by muse, varscan2
- SARDH | c.909G>C p.G303= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100061086; called by muse, mutect2, varscan2
- SEPTIN9 | c.1629G>A p.T543= (on ENST00000427177 / NM_001113491.2; = p.T525= on NM_006640.4) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs373382274; called by muse, mutect2, varscan2
- SF1 | c.858C>T p.G286= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99918630; called by muse, mutect2, varscan2
- SF3B1 | c.1683C>T p.Y561= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100135424; called by muse, mutect2, varscan2
57 further variants in this file (0 protein-altering or splice-affecting, 39 silent, 18 other) are not listed here.
